Somatic mutation profile of tumor specimen TCGA-EJ-A46I-01A (aliquot TCGA-EJ-A46I-01A-12D-A26M-08) from TCGA case TCGA-EJ-A46I, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 57.6 years (21,046 days).
Specimen TCGA-EJ-A46I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae5c0ac6-f865-4568-9aea-13739b0d1498.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-A46I-10A (Blood Derived Normal), aliquot TCGA-EJ-A46I-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cee37888-660f-4266-9bba-7fd14481192c

The open-access MAF lists 8 somatic variants for this specimen: 8 protein-altering or splice-affecting.
By variant classification: Missense Mutation 8.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP2B2 | c.1431G>T p.E477D (on ENST00000352432; = p.E443D on NM_001683.5) | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59491941; called by muse, mutect2
- CDH18 | c.859G>A p.V287I | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.99); catalogued as COSV56919401; called by muse, mutect2
- DTNA | c.1259C>A p.P420H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV52011792; called by muse, mutect2
- EXTL1 | c.1189T>A p.F397I | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV100959106; called by muse, mutect2, varscan2
- MBD3 | c.193C>A p.R65S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); catalogued as COSV50084292, COSV50085289; called by muse, mutect2
- XPO4 | c.548A>T p.H183L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55009512; called by muse, mutect2, varscan2
- CDC73 | c.1339G>A p.V447M | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- HIVEP1 | c.4608G>T p.Q1536H | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
